Somatic mutation profile of tumor specimen 0DJ4C1 from CCDI case PBBWLR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,142 days).
Specimen 0DJ4C1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb5be034-bcb5-4c18-a8c3-4f4a00b9e554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ4CB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e6b5051-20fc-49b2-ab0c-a39c4c33127f

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Intron 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKD1 | c.9926C>T p.T3309M | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs761055827; called by muse, mutect2, varscan2
- SP140L | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 28/1060 reads (3%) | catalogued as rs1376655066; called by muse, mutect2
- TRAF3IP1 | c.1172C>G p.A391G | Missense Mutation (SNP) | VAF 100/612 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1266842284; called by muse, mutect2, varscan2
- TRIM22 | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 47/428 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV66090890; called by muse, mutect2
- ZNRF1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as rs776579117; called by mutect2, varscan2
- AGBL2 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 104/600 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EPG5 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 30/802 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.069); called by muse, mutect2
- GSE1 | c.1489dup p.W497Lfs*63 | Frame Shift Ins (INS) | VAF 94/192 reads (49%) | called by mutect2, varscan2
- LDB1 | c.404G>T p.G135V (on ENST00000425280 / NM_001321612.2; = p.G99V on NM_003893.5) | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPT1 | c.691A>T p.N231Y (on ENST00000433473; = p.N232Y on NM_000310.4) | Missense Mutation (SNP) | VAF 114/1353 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- PRKG1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- TBC1D10B | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2
- XKR3 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- FLG | c.3390C>A p.A1130= | Silent (SNP) | VAF 14/265 reads (5%) | called by muse, mutect2
- GFPT2 | c.1320C>T p.R440= | Silent (SNP) | VAF 69/499 reads (14%) | catalogued as rs757240985, COSV99517275; called by muse, mutect2, varscan2
- IL4R | c.543A>G p.E181= | Silent (SNP) | VAF 99/320 reads (31%) | called by muse, mutect2, varscan2
- OR5T1 | c.477T>A p.A159= | Silent (SNP) | VAF 140/391 reads (36%) | called by muse, mutect2, varscan2
- PIK3CB | c.525A>G p.T175= | Silent (SNP) | VAF 208/680 reads (31%) | called by muse, mutect2, varscan2
- PODNL1 | c.633C>T p.L211= | Silent (SNP) | VAF 67/572 reads (12%) | catalogued as rs753390515; called by mutect2, varscan2
- RPIA | c.69G>A p.G23= | Silent (SNP) | VAF 48/395 reads (12%) | catalogued as rs769685619, COSV52170421; called by muse, mutect2, varscan2
- TRPM6 | c.5292G>A p.A1764= | Silent (SNP) | VAF 93/1114 reads (8%) | catalogued as rs552880023; called by muse, mutect2
- COG1 | c.2805+28C>T | Intron (SNP) | VAF 369/823 reads (45%) | catalogued as rs372555370; called by muse, mutect2, varscan2
- CRTC2 | c.608-59G>C | Intron (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- GBX2 | c.523+194C>A | Intron (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- RPL24 | c.393+33A>G | Intron (SNP) | VAF 26/524 reads (5%) | called by muse, mutect2
